Somatic mutation profile of tumor specimen TCGA-XF-A9SX-01A (aliquot TCGA-XF-A9SX-01A-21D-A391-08) from TCGA case TCGA-XF-A9SX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 63.9 years (23,349 days).
Specimen TCGA-XF-A9SX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f800f82d-0df9-415e-b315-6cffdb391caf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SX-10A (Blood Derived Normal), aliquot TCGA-XF-A9SX-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94ad4c90-79f0-42a5-85d2-bed43dadefb8

The open-access MAF lists 117 somatic variants for this specimen: 94 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 21, Nonsense Mutation 12, Frame Shift Del 3, Splice Site 2, Intron 2, Translation Start Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TACR3 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as rs727505375, CM103250, COSV59200874; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.1808G>A p.C603Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as rs868712999, COSV52944007; called by muse, mutect2, varscan2
- ANKRD35 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212395079, COSV62909770; called by muse, mutect2, varscan2
- ARAF | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.342); catalogued as rs1345707414, COSV51691626; called by muse, mutect2, varscan2
- ARHGAP24 | c.1240A>G p.R414G (on ENST00000395184 / NM_001025616.3; = p.R321G on NM_031305.3) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.815); catalogued as rs1161531361, COSV51987349; called by muse, mutect2, varscan2
- ATG2B | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); catalogued as COSV63422108; called by muse, mutect2, varscan2
- ATP6AP2 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV65797321; called by muse, mutect2, varscan2
- BEND6 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs866381843, COSV100876782, COSV66068311; called by muse, mutect2, varscan2
- BPTF | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58832933; called by muse, mutect2, varscan2
- C15orf39 | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62295922; called by muse, mutect2, varscan2
- CBL | c.1332G>T p.R444S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV50631295; called by muse, varscan2
- CCAR1 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1302769076, COSV56267999; called by muse, mutect2, varscan2
- CCDC141 | c.2804G>T p.R935L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55370416; called by muse, mutect2, varscan2
- CDH1 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as CM044862, COSV55742251; called by muse, mutect2, varscan2
- CDH12 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101203218, COSV66392701; called by muse, mutect2, varscan2
- CDHR2 | c.3640T>C p.Y1214H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1380793959, COSV99991710, COSV99992158; called by muse, mutect2
- CEP112 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67137092; called by muse, mutect2, varscan2
- CEP164 | c.3913G>A p.D1305N | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV54039054, COSV54042392; called by muse, mutect2, varscan2
- CFTR | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50056108; called by muse, mutect2
- CLRN2 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV71825164; called by muse, mutect2, varscan2
- CLTCL1 | c.3694G>A p.V1232I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs781913317, COSV54226380; called by muse, mutect2, varscan2
- CNGB1 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99202661; called by muse, mutect2, varscan2
- CSMD1 | c.2363T>C p.I788T (on ENST00000520002; = p.I787T on NM_033225.6) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV59293297; called by muse, mutect2, varscan2
- CUL1 | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57387223; called by muse, mutect2, varscan2
- CUL4B | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV60685418; called by muse, mutect2
- DAZAP1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV51831705; called by muse, mutect2, varscan2
- DIAPH1 | c.3293A>C p.Q1098P | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV53879458; called by muse, mutect2, varscan2
- EFHC2 | c.1873C>T p.H625Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs1355095148, COSV59092475; called by muse, mutect2, varscan2
- EHBP1L1 | c.1679G>A p.W560* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100499915; called by muse, mutect2, varscan2
- EOLA2 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100778079; called by muse, mutect2
- EP300 | c.4567G>T p.E1523* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV54332083; called by muse, mutect2, varscan2
- EPC1 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV53923654; called by muse, mutect2
- FANCB | c.1070T>C p.F357S | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60759082; called by muse, mutect2, varscan2
- FAT1 | c.4679C>T p.P1560L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374571513, COSV71672139; called by muse, mutect2, varscan2
- FCHO1 | c.393C>A p.S131R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV53181258; called by muse, mutect2, varscan2
- FGG | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.203); catalogued as rs1476647015, COSV60194744, COSV60196187; called by muse, mutect2, varscan2
- FLG | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs764904407, COSV64238067; called by muse, mutect2, varscan2
- FMN2 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.324); catalogued as rs1479970087, COSV100145528; called by muse, varscan2
- FOLH1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV57046592, COSV57056518; called by muse, mutect2, varscan2
- GPR50 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV54437418; called by muse, mutect2, varscan2
- HFM1 | c.2681-2A>T p.X894_splice | Splice Site (SNP) | VAF 9/63 reads (14%) | catalogued as COSV54022995; called by muse, mutect2, varscan2
- HUWE1 | c.12005G>T p.R4002L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53337404, COSV53359871; called by muse, mutect2
- IL1RAPL1 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV56243698, COSV56265857; called by muse, mutect2
- KARS1 | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1419572448, COSV56691064; called by muse, mutect2, varscan2
- MAGEB1 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as rs764364549, COSV66775386; called by muse, mutect2, varscan2
- MAK | c.495T>G p.Y165* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100504454; called by muse, mutect2, varscan2
- MAP1A | c.7709C>T p.P2570L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55806849; called by muse, mutect2, varscan2
- MST1R | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV56565726; called by muse, mutect2, varscan2
- MYPN | c.1617C>G p.S539R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62732056; called by muse, mutect2, varscan2
- NAP1L2 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); catalogued as COSV65172257, COSV65172387; called by muse, mutect2, varscan2
- NCAPD3 | c.3677A>G p.Y1226C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1369149011, COSV73187761; called by muse, mutect2, varscan2
- NDN | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100086478; called by muse, mutect2, varscan2
- NEB | c.16432T>G p.L5478V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV50841739; called by mutect2, varscan2
- NPEPPS | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as rs1028690165, COSV59101228; called by muse, mutect2
- NUP98 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as rs1285678667, COSV61429612; called by muse, mutect2, varscan2
- OR13H1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100088467, COSV58547177; called by muse, mutect2, varscan2
- OR4A15 | c.784A>G p.T262A | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV59033958; called by mutect2, varscan2
- OR4A47 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV71444864; called by muse, mutect2, varscan2
- OR4Q3 | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 25/312 reads (8%) | catalogued as COSV100057106; called by muse, mutect2
- OR4X1 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as rs151032486; called by muse, mutect2, varscan2
- OR51B2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60916136; called by muse, mutect2, varscan2
- OR52B2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1423717450, COSV73209259; called by muse, mutect2, varscan2
- PI4K2A | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as COSV101034259; called by muse, mutect2, varscan2
- PIP5K1B | c.1337T>C p.F446S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55242868, COSV55250573; called by muse, mutect2, varscan2
- PKD2L2 | c.1732T>A p.S578T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV50364511; called by muse, varscan2
- PLEKHB2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1213948708, COSV52174993; called by muse, varscan2
- PPARD | c.48G>C p.E16D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.899); catalogued as rs1410976918, COSV100283151; called by muse, mutect2
- PPARGC1B | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as COSV58525824; called by muse, mutect2
- PSME4 | c.5222A>G p.K1741R | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV66363721; called by muse, mutect2, varscan2
- PTGER2 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55418357; called by muse, mutect2, varscan2
- RAB21 | c.429del p.I144Ffs*37 | Frame Shift Del (DEL) | VAF 13/109 reads (12%) | catalogued as COSV54230529; called by mutect2, pindel, varscan2
- RB1 | c.1960+1dup | Frame Shift Ins (INS) | VAF 9/39 reads (23%) | catalogued as COSV57296305; called by mutect2, pindel, varscan2
- RBMS3 | c.400-2A>T p.X134_splice | Splice Site (SNP) | VAF 28/131 reads (21%) | catalogued as COSV56135398; called by muse, mutect2, varscan2
- RSPH3 | c.172A>G p.R58G | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51921414; called by muse, mutect2, varscan2
- SEMA3D | c.2067G>A p.M689I | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52389109; called by muse, mutect2, varscan2
- SLC20A2 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60602257; called by muse, mutect2, varscan2
- SLC22A8 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs747832381, COSV60324059; called by muse, mutect2, varscan2
- SLC45A2 | c.1056T>G p.Y352* | Nonsense Mutation (SNP) | VAF 68/202 reads (34%) | catalogued as rs765213151, COSV99672801; called by muse, mutect2, varscan2
- SMPD3 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54710870; called by muse, mutect2, varscan2
- SPG7 | c.2160G>T p.A720= (on ENST00000268704; = p.A727= on NM_003119.4) | Splice Region (SNP) | VAF 6/11 reads (55%) | catalogued as rs753423781, COSV51948358; called by muse, mutect2, varscan2
- STK33 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV59397691, COSV59404490; called by muse, mutect2, varscan2
- TBC1D23 | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV61367028; called by muse, mutect2, varscan2
- TG | c.7574A>G p.Q2525R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV55067974; called by muse, mutect2, varscan2
- TMC5 | c.2557G>T p.A853S (on ENST00000396229 / NM_001105248.1; = p.A607S on NM_024780.5) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); catalogued as COSV54901636, COSV54910735; called by muse, mutect2, varscan2
- TNXB | c.5278G>A p.G1760R (on ENST00000647633; = p.G1513R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs771301700, COSV64474964; called by muse, mutect2, varscan2
- TRPA1 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.846); catalogued as COSV51554874, COSV51556908; called by muse, mutect2, varscan2
- TTI1 | c.739A>G p.M247V | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV65060792; called by muse, mutect2, varscan2
- ZHX2 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58711035; called by muse, mutect2, varscan2
- ZNF816 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54410624; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2848del p.H950Tfs*? | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- NCOA4 | c.807T>A p.Y269* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | called by muse, mutect2, varscan2
- TMEM236 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 109/603 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP12 | c.1084_1088del p.Y362Pfs*47 | Frame Shift Del (DEL) | VAF 25/115 reads (22%) | called by mutect2, pindel, varscan2
- ACTL9 | c.982C>T p.L328= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV61005075, COSV61007595; called by muse, mutect2, varscan2
- ACTL9 | c.621C>T p.P207= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV61005082; called by muse, mutect2
- BCKDK | c.925C>T p.L309= | Silent (SNP) | VAF 4/73 reads (5%) | catalogued as COSV99570688; called by muse, mutect2
- BOD1L1 | c.9147G>A p.A3049= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs747400099, COSV99239559; called by muse, mutect2
- CADPS | c.3132T>A p.T1044= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV51870746; called by muse, mutect2, varscan2
- CSMD1 | c.4338T>A p.P1446= (on ENST00000520002; = p.P1445= on NM_033225.6) | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV59293269; called by muse, mutect2, varscan2
- CTPS2 | c.606C>T p.R202= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs768155926, COSV63721567, COSV63722444; called by muse, mutect2, varscan2
- FAM131B | c.351C>T p.S117= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs776864500, COSV68125661; called by muse, mutect2, varscan2
- FBN3 | c.5292C>T p.V1764= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs767010079, COSV54455197; called by muse, mutect2, varscan2
- LENG8 | c.105G>A p.E35= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100457619; called by muse, mutect2
- MSL3 | c.1053C>A p.S351= (on ENST00000312196 / NM_078629.4; = p.S185= on NM_006800.4) | Silent (SNP) | VAF 26/143 reads (18%) | catalogued as COSV56491978; called by muse, mutect2, varscan2
- NPHS1 | c.211C>T p.L71= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1223661976, COSV62286765; called by muse, mutect2, varscan2
- OR2G2 | c.729C>G p.T243= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV60739690; called by muse, mutect2, varscan2
- OR4C11 | c.861G>A p.L287= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1318262582, COSV100155247, COSV56352450; called by muse, mutect2, varscan2
- OR5D18 | c.744C>T p.A248= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs765426060, COSV61736458; called by muse, mutect2, varscan2
- ROBO2 | c.2904C>T p.L968= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV59900906; called by muse, mutect2, varscan2
- RYR3 | c.831C>T p.N277= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs897878116, COSV66780943; called by muse, mutect2, varscan2
- SERPING1 | c.174C>A p.P58= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV53541726; called by muse, mutect2, varscan2
- SIPA1L1 | c.1641G>T p.L547= | Silent (SNP) | VAF 33/261 reads (13%) | catalogued as COSV62168964; called by muse, mutect2, varscan2
- SLC25A35 | c.144T>C p.H48= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs367552065; called by muse, mutect2, varscan2
- SYNRG | c.1554A>G p.K518= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- RARB | c.179-32425G>T | Intron (SNP) | VAF 38/190 reads (20%) | catalogued as COSV58065600; called by muse, mutect2, varscan2
- TTN | c.10361-5150del | Intron (DEL) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
